Somatic mutation profile of tumor specimen TCGA-ZB-A964-01A (aliquot TCGA-ZB-A964-01A-11D-A428-09) from TCGA case TCGA-ZB-A964, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 70.8 years (25,861 days).
Specimen TCGA-ZB-A964-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5200c11a-4f73-4a87-bc33-97b7bbf523d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A964-10A (Blood Derived Normal), aliquot TCGA-ZB-A964-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be4ac3aa-37b5-46e8-a26c-723067c087d2

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 188/469 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HRAS | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 18/32 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54236714, COSV54237107; called by muse, mutect2, varscan2
- BLZF1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as rs1275226814; called by muse, mutect2
- PCSK7 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs781110023, COSV58006418; called by muse, mutect2, varscan2
- TLR2 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs376311320; called by muse, mutect2, varscan2
- TRPT1 | c.441C>A p.C147* (on ENST00000317459 / NM_001160393.1; = p.C98* on NM_031472.4) | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99655669; called by muse, mutect2
- VARS1 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs780115933; called by muse, mutect2, varscan2
- ADGRE3 | c.368C>A p.S123* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- DNAJC27 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GPD2 | c.1970T>G p.V657G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OPLAH | c.1896C>A p.D632E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); called by mutect2, varscan2
- PUS1 | c.1133T>C p.I378T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF713 | c.599G>T p.G200V (on ENST00000633730 / NM_001366796.2; = p.G213V on NM_182633.3) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); called by muse, mutect2
- LRIG2 | c.1629G>T p.V543= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- NPAT | c.2694T>A p.T898= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs749480404; called by muse, mutect2, varscan2
